Gene-level copy-number profile of specimen HCM-BROD-0958-C56-85B from HCMI case HCM-BROD-0958-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.8 years (22,920 days).
Specimen HCM-BROD-0958-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 342e2770-a992-45a6-90c3-16280f7d90dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0958-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/9b5db421-0554-4160-b449-2cb30bf3ac61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 14,182; copy number 2: 40,159; copy number 3: 4,039; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:18,201,501–18,598,328, 22 genes: AC008785.1, AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2, AC136618.1, ABCC6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
